Somatic mutation profile of tumor specimen TCGA-S6-A8JX-01A (aliquot TCGA-S6-A8JX-01A-11D-A435-10) from TCGA case TCGA-S6-A8JX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 27.3 years (9,963 days).
Specimen TCGA-S6-A8JX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3df53c6-278e-4934-8424-95a279b7dc6a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S6-A8JX-10A (Blood Derived Normal), aliquot TCGA-S6-A8JX-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5716590-a5a3-438f-8365-16e5f3a60262

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCL6 | c.164C>G p.T55R | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56902940; called by muse, mutect2, varscan2
- KCNH6 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs774807503, COSV59005860; called by muse, mutect2, varscan2
- MLX | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTAGE8 | c.2333G>A p.*778= | Silent (SNP) | VAF 54/608 reads (9%) | called by muse, varscan2
- EIF4G3 | c.2343T>C p.T781= | Silent (SNP) | VAF 32/100 reads (32%) | called by muse, mutect2, varscan2
- HOXC11 | c.480C>T p.C160= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs1235842621; called by muse, mutect2, varscan2
- TAF1 | c.5002-363G>T | Intron (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
